Somatic mutation profile of tumor specimen ALCH-B4SX-TTP1-A (aliquot ALCH-B4SX-TTP1-A-1-0-D-A81V-36) from ALCHEMIST case ALCH-B4SX, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 74.4 years (27,163 days).
Specimen ALCH-B4SX-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0bfd05cc-caed-4dac-b2d5-a806181f15ad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4SX-NB1-A (Blood Derived Normal), aliquot ALCH-B4SX-NB1-A-1-0-D-A81V-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/35053af6-23b3-4acf-b15c-ea8197cbf37e

The open-access MAF lists 26 somatic variants for this specimen: 17 protein-altering or splice-affecting, 4 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 4, Intron 3, In Frame Del 2, Frame Shift Del 1, RNA 1, Frame Shift Ins 1, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2253_2276del p.S752_I759del | In Frame Del (DEL) | VAF 14/172 reads (8%) | hotspot (GDC flag); catalogued as rs727504232, COSV51766231; ClinVar: drug response; called by mutect2, pindel
- TP53 | c.96+1G>A p.X32_splice | Splice Site (SNP) | VAF 14/76 reads (18%) | hotspot (GDC flag); catalogued as CS167193, COSV52662718, COSV52757202, COSV53162510; called by muse, varscan2
- AHNAK2 | c.4980G>T p.M1660I | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as rs564987042; called by muse, mutect2, varscan2
- HMCN1 | c.2369G>T p.G790V | Missense Mutation (SNP) | VAF 15/183 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs752448870; called by muse, mutect2
- PCDHA7 | c.1684G>A p.A562T | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.12); catalogued as rs781892908, COSV65347540; called by muse, mutect2, varscan2
- PCGF2 | c.781G>A p.D261N | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as rs751218338; called by muse, mutect2, varscan2
- VKORC1 | c.165C>G p.F55L | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.989); catalogued as rs1392107723; called by muse, varscan2
- ATP13A2 | c.339_340del p.E114Gfs*81 | Frame Shift Del (DEL) | VAF 16/77 reads (21%) | called by mutect2, pindel, varscan2
- FAT4 | c.11466A>T p.R3822S | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- GOLGA6D | c.572G>A p.S191N | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- OMG | c.626A>T p.Q209L | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- PCDHB14 | c.1424_1425insA p.T476Hfs*200 | Frame Shift Ins (INS) | VAF 18/114 reads (16%) | called by mutect2, pindel, varscan2
- RBM6 | c.1235G>A p.R412K | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- RNF157 | c.505C>A p.Q169K | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TMEM67 | c.1472C>G p.A491G | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- UHRF1BP1 | c.3051_3068del p.E1017_H1023delinsD | In Frame Del (DEL) | VAF 10/90 reads (11%) | called by mutect2, pindel
- USP16 | c.1171G>A p.D391N | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.811); called by mutect2, varscan2
- EPYC | c.420G>A p.P140= | Silent (SNP) | VAF 20/133 reads (15%) | catalogued as rs1565871112, COSV99664928; called by muse, varscan2
- PCSK5 | c.456C>T p.I152= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as rs771576413, COSV65095991; called by muse, mutect2, varscan2
- TARS2 | c.1176C>T p.D392= | Silent (SNP) | VAF 17/90 reads (19%) | catalogued as rs374221932; called by muse, mutect2, varscan2
- UBASH3A | c.1209C>T p.H403= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as rs142759802; called by muse, mutect2, varscan2
- DOCK8 | c.53+5745A>G | Intron (SNP) | VAF 4/26 reads (15%) | catalogued as rs1459789954; called by mutect2, varscan2
- FAM172BP | n.985A>G | RNA (SNP) | VAF 11/68 reads (16%) | called by muse, mutect2
- GLRA2 | c.-53C>A | 5'UTR (SNP) | VAF 19/56 reads (34%) | called by muse, mutect2
- KIF1B | c.2115+6349G>A | Intron (SNP) | VAF 27/103 reads (26%) | catalogued as rs367630398; called by muse, mutect2, varscan2
- STK32A | c.1033-23T>C | Intron (SNP) | VAF 14/80 reads (18%) | called by muse, mutect2, varscan2
